Somatic mutation profile of tumor specimen ALCH-AENU-TTP1-A (aliquot ALCH-AENU-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AENU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,304 days).
Specimen ALCH-AENU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb6ff7f2-6390-4b45-856a-8239996bf306.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENU-NB1-A (Blood Derived Normal), aliquot ALCH-AENU-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd3a3edc-b2e9-4d72-ae36-bdd5fe8fa31e

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Intron 2, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCP110 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372951911; called by muse, mutect2, varscan2
- CDC14C | c.1492G>A p.E498K (on ENST00000428251; = p.E391K on NM_152627.3) | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs758667733; called by muse, mutect2, varscan2
- EGFR | c.2263G>T p.A755S | Missense Mutation (SNP) | VAF 90/569 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV51800786; called by muse, varscan2
- EGFR | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 94/578 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51783384, COSV51786456; called by muse, varscan2
- GPATCH8 | c.493-1G>C p.X165_splice | Splice Site (SNP) | VAF 44/474 reads (9%) | catalogued as COSV100132392, COSV59196101; called by muse, mutect2
- GPRC6A | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV59955197; called by muse, mutect2, varscan2
- IQCN | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs200263958; called by muse, mutect2, varscan2
- MTX3 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs146367288; called by muse, mutect2, varscan2
- NEDD9 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs779372741; called by muse, mutect2
- PCDHGA1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 49/401 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV65294890; called by muse, mutect2, varscan2
- SBF1 | c.4510G>A p.G1504S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs748897740; called by muse, mutect2, varscan2
- SLC6A3 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 92/509 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54362925; called by muse, mutect2, varscan2
- THRA | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52842004; called by muse, mutect2
- TP53 | c.690dup p.T231Hfs*9 | Frame Shift Ins (INS) | VAF 61/340 reads (18%) | catalogued as COSV53804661; called by mutect2, pindel, varscan2
- ASTN2 | c.1351T>G p.C451G (on ENST00000313400 / NM_001365069.1; = p.C400G on NM_014010.5) | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- HMGB2 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP10-7 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MLLT6 | c.2883G>A p.P961= | Splice Region (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- MMP13 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 54/396 reads (14%) | called by muse, mutect2, varscan2
- PIGV | c.1475G>T p.W492L | Missense Mutation (SNP) | VAF 43/530 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGS14 | c.1112A>G p.N371S | Missense Mutation (SNP) | VAF 119/298 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SCGB3A2 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SLK | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 15/221 reads (7%) | called by muse, mutect2
- SLK | c.3053A>C p.E1018A | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DLGAP2 | c.411G>A p.P137= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs1371030171, COSV101421521, COSV101422654; called by muse, mutect2, varscan2
- FAM131C | c.240G>A p.V80= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- ITGA11 | c.1029T>C p.D343= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs749177338; called by muse, mutect2, varscan2
- ITPR1 | c.4158G>A p.T1386= (on ENST00000354582; = p.T1371= on NM_002222.7) | Silent (SNP) | VAF 23/234 reads (10%) | catalogued as rs748093001; called by muse, mutect2, varscan2
- RALGAPA2 | c.2649T>C p.A883= | Silent (SNP) | VAF 43/196 reads (22%) | called by muse, mutect2, varscan2
- RTN2 | c.12C>T p.V4= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2
- SLC34A1 | c.426C>A p.I142= | Silent (SNP) | VAF 58/645 reads (9%) | called by muse, mutect2
- TP63 | c.558C>T p.T186= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as rs200355416, COSV99286077; called by muse, mutect2, varscan2
- TRIM72 | c.72C>T p.P24= | Silent (SNP) | VAF 63/336 reads (19%) | catalogued as rs897606182, COSV57251779; called by muse, mutect2, varscan2
- AC079154.1 | n.1025T>G | RNA (SNP) | VAF 39/312 reads (13%) | called by muse, mutect2, varscan2
- FBN1 | c.164+40del | Intron (DEL) | VAF 29/186 reads (16%) | called by mutect2, pindel, varscan2
- MPV17 | c.71-58C>T | Intron (SNP) | VAF 32/183 reads (17%) | catalogued as rs768874741; called by muse, mutect2, varscan2
- NAGA | c.-48dup | 5'UTR (INS) | VAF 48/303 reads (16%) | called by mutect2, pindel, varscan2
- TBX2 | chr17:61412046 C>T | 3'Flank (SNP) | VAF 34/328 reads (10%) | called by muse, mutect2, varscan2
